Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A74J, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A74J-01A (Primary Tumor).

Pathology Report for

Date of Surgery:

Diagnosis:

Left temporal brain tumor

Oligoastrocytoma, grade II

MIB-1 LI= 5.1%

Discussion:

The neoplastic cells are positive for IDH1 but negative for p53, most consistent with oligodendroglia lineage. Scattered MIB-1 reactive cells are present with a labeling index of 5.1%.

Microscopic Description:

Sections demonstrate a variably but generally moderately hypercellular diffusely infiltrating glial neoplasm. Rare markedly hypercellular foci are seen. ATPase consistently mild. The tumor includes both classic oligodendroglioma and fibrillary astrocytoma phenotypes. A rare mitotic figure is seen in the most hypercellular region. There is no microvascular proliferation or necrosis.

ICD-O-3
Oligoastrocytoma, grade II
9382/3
Site C4CF Brain, supratentorial NOS C71.0
path
② Brain, temporal lobe C71.2
JW 8/27/13

Source: NCI Genomic Data Commons file abbebd45-ce8f-4759-9bba-1f5ba8e9d0f4 (TCGA-HT-A74J.458CC740-C271-4F99-99CE-3101FF24D4B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).